Gene-level copy-number profile of tumor specimen TCGA-AA-A010-01A from TCGA case TCGA-AA-A010, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.3 years (16,922 days).
Specimen TCGA-AA-A010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.da230166-a141-43f3-ab90-60d83429446a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A010-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b216d328-3ec1-47fc-b2e7-77120863df6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 616; copy number 1: 2,599; copy number 2: 55,990; copy number 3: 478; copy number 4: 312; copy number 5: 98; copy number 6: 167; copy number 7: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A010-01A-01D-A008-01): tumor purity 0.77, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,435,232–75,538,029, 1 gene (within-gene range 0–2): LINC02018.
- chr3:75,521,803–75,590,649, 4 genes: SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr6:33,091,753–33,097,295, 1 gene: HLA-DPA2.
- chr12:11,351,823–11,395,566, 1 gene: PRB1.
- chr20:39,655,325–39,663,552, 1 gene (within-gene range 0–2): AL132981.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 271 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,764,503–106,344,833, 98 genes, copy number 5 (broad region; genes not listed).
- chr15:19,878,555–23,407,335, 167 genes, copy number 6 (broad region; genes not listed).
- chr17:46,029,916–46,225,389, 1 gene, copy number 7 (within-gene range 2–7): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 7: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 265. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
